Somatic mutation profile of tumor specimen TCGA-3H-AB3X-01A (aliquot TCGA-3H-AB3X-01A-11D-A39R-32) from TCGA case TCGA-3H-AB3X, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.2 years (22,702 days).
Specimen TCGA-3H-AB3X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f65cf0da-72ac-438f-b01a-841d20a42ee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3X-10A (Blood Derived Normal), aliquot TCGA-3H-AB3X-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51d1eb25-0fda-42f4-b274-b25e029b94a9

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBP5 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100600157; called by muse, mutect2, varscan2
- LPAR2 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as rs1408714373; called by muse, mutect2, varscan2
- MAPK8 | c.1204A>G p.M402V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs774869055; called by muse, mutect2, varscan2
- SHROOM1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100167237; called by muse, mutect2, varscan2
- STC1 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99282304; called by muse, mutect2, varscan2
- TEX15 | c.1808A>G p.Q603R (on ENST00000256246; = p.Q986R on NM_001350162.2) | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs757126871; called by muse, mutect2, varscan2
- USP16 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs377322556; called by muse, mutect2, varscan2
- ATF1 | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- EFNB2 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- LRP1 | c.10738T>C p.F3580L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- MATN3 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OR5AK2 | c.186del p.L63Yfs*29 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, varscan2
- SLC22A14 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- SPRTN | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- STIL | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STKLD1 | c.589T>A p.F197I | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZFHX4 | c.8190_8220del p.F2730Lfs*29 | Frame Shift Del (DEL) | VAF 55/191 reads (29%) | called by mutect2, pindel
- ZNF536 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF687 | c.3704G>A p.G1235E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- CFAP36 | c.426C>T p.G142= | Silent (SNP) | VAF 39/113 reads (35%) | called by muse, mutect2, varscan2
- IFNA8 | c.69C>T p.G23= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- MKRN3 | c.258G>A p.P86= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs992964077, COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- TRIM14 | c.882G>A p.L294= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1334494193, COSV99271603; called by muse, mutect2, varscan2
